Gene-level copy-number profile of tumor specimen TCGA-B6-A1KN-01A from TCGA case TCGA-B6-A1KN, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 58.0 years (21,183 days).
Specimen TCGA-B6-A1KN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.c5a9ae9d-9331-48b7-a5c9-a37102897313.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B6-A1KN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/02e8a47b-38fd-4afb-bb8c-883da7dc970b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 6; copy number 2: 12,220; copy number 3: 14,398; copy number 4: 26,781; copy number 5: 2,654; copy number 6: 1,175; copy number 7: 102; copy number 8: 910; copy number 9: 234; copy number 10: 328; copy number 12: 51; copy number 13: 108; copy number 14: 188; copy number 15: 387; copy number 16: 31; copy number 17: 2; copy number 18: 6; copy number 20: 1; copy number 21: 54; copy number 23: 4; copy number 24: 13; copy number 25: 36; copy number 27: 67; copy number 43: 62.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B6-A1KN-01A-11D-A13J-01): tumor purity 0.56, ploidy 3.63, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,356 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:6,534,697–8,760,447, 43 genes, copy number 10–13 (within-gene range 8–13): CNN3P1, LY86, AL031123.2, AL031123.3, AL031123.1, AL031123.4, AL031123.5, AL136361.1, BTF3P7, AL158817.1, RN7SL554P, AL139390.1, RREB1, AL355336.1, Y_RNA, AL589644.1, AL139095.5, SSR1, AL139095.4, CAGE1, AL139095.1, AL139095.2, AL139095.3, RIOK1, HNRNPLP1, AL138878.1, AL138878.2, AL031058.1, DSP, SNRNP48, AL390026.1, BMP6, TXNDC5, BLOC1S5-TXNDC5, AL096800.1, PIP5K1P1, BLOC1S5, EEF1E1-BLOC1S5, EEF1E1, AL355499.1, AL355499.2, AL359378.1, SLC35B3.
- chr8:20,655,184–22,275,162, 31 genes, copy number 10 (within-gene range 2–10): AC018541.1, TMEM97P2, AC015468.3, AC021613.1, AC015468.1, AC015468.2, LINC02153, AC103719.1, AC021613.2, AC021613.3, AC021355.1, GFRA2, OR6R2P, DOK2, XPO7, NPM2, FGF17, DMTN, FAM160B2, NUDT18, HR, REEP4, LGI3, SFTPC, BMP1, AC105206.1, AC105206.3, PHYHIP, MIR320A, POLR3D, AC105206.2.
- chr8:27,063,996–27,545,564, 9 genes, copy number 10 (within-gene range 2–10): AC067904.2, AC090150.2, AC090150.1, STMN4, TRIM35, PTK2B, MIR6842, CHRNA2, EPHX2.
- chr8:35,235,475–39,417,378, 90 genes, copy number 13–27 (broad region; genes not listed).
- chr8:39,522,976–39,730,065, 2 genes, copy number 17 (within-gene range 4–17): AC123767.1, ADAM18.
- chr8:40,530,590–42,405,937, 40 genes, copy number 12 (within-gene range 2–12): ZMAT4, AC048387.1, RNU6-356P, SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P, SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23, DKK4, VDAC3.
- chr8:83,912,713–84,164,564, 3 genes, copy number 16: AC015522.1, TPM3P3, AC012400.1.
- chr8:86,214,063–145,066,685, 924 genes, copy number 10–21 (within-gene range 8–21) (broad region; genes not listed).
- chr12:7,304,284–7,479,897, 3 genes, copy number 23: ACSM4, CD163L1, AC131206.1.
- chr14:39,147,811–39,388,513, 9 genes, copy number 9 (within-gene range 2–9): TRAPPC6B, AL109628.2, RPL7AP2, AL132639.3, PNN, AL132639.1, YTHDF2P1, MIA2, AL132639.2.
- chr17:37,686,431–37,884,743, 3 genes, copy number 24 (within-gene range 2–24): HNF1B, AC243571.1, YWHAEP7.
- chr17:38,765,689–40,885,242, 107 genes, copy number 24–43 (broad region; genes not listed).
- chr17:40,922,700–40,937,646, 1 gene, copy number 25 (within-gene range 8–25): KRT23.
- chr19:17,009,189–18,049,090, 63 genes, copy number 10 (broad region; genes not listed).
- chr20:10,875,333–10,909,279, 1 gene, copy number 23 (within-gene range 2–23): AL050403.1.
- chr20:11,345,383–11,345,855, 1 gene, copy number 20: RPS11P1.
- chr20:12,865,202–16,053,197, 18 genes, copy number 9–18 (within-gene range 2–18): LINC01722, AL078623.1, AL133331.1, LINC01723, SPTLC3, AL109983.1, ISM1, AL050320.1, AL121782.1, TASP1, GAPDHP2, ESF1, NDUFAF5, SEL1L2, RNU6-278P, MACROD2, RPS3P1, AIMP1P1.
- chr20:14,757,563–15,619,819, 8 genes, copy number 9: RPS10P2, MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P, RNA5SP475, AL121584.1, ENSAP1.

Autosomal genes at a single copy (total copy number 1): 6. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
